Gene-level copy-number profile of tumor specimen TCGA-E7-A7PW-01A from TCGA case TCGA-E7-A7PW, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 63.1 years (23,057 days).
Specimen TCGA-E7-A7PW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.ba094b4a-d31c-49b7-acaa-fccb0e427f8e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-E7-A7PW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4ef482e9-0ab3-42f2-80b3-7a258cde983c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 14,123; copy number 3: 26,421; copy number 4: 13,341; copy number 5: 2,399; copy number 6: 2,261; copy number 7: 472; copy number 8: 267; copy number 9: 162; copy number 10: 100; copy number 12: 17; copy number 13: 80; copy number 15: 2; copy number 16: 58; copy number 17: 3; copy number 20: 3; copy number 22: 26; copy number 23: 8; copy number 27: 34; copy number 33: 12; copy number 34: 8; copy number 45: 1; copy number 46: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-E7-A7PW-01A-11D-A34T-01): tumor purity 0.84, ploidy 3.39, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,269 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:161,663,147–167,166,479, 108 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr2:58,427,799–59,063,766, 1 gene, copy number 7 (within-gene range 5–7): LINC01122.
- chr2:59,014,354–60,938,604, 30 genes, copy number 7: AC007092.1, LINC01793, AC007100.1, AC007179.2, AC007179.1, AC007179.3, RNU6-508P, RNA5SP94, AC007100.2, AC007132.1, MIR4432HG, AC007381.1, RNU1-32P, MIR4432, BCL11A, AC009970.1, RN7SL361P, IFITM3P9, RPL26P13, RNU6-612P, ATP1B3P1, PAPOLG, LINC01185, RN7SL632P, RPL21P33, REL, RNU4-51P, AC010733.1, NONOP2, RPS12P3.
- chr2:68,117,026–80,870,190, 259 genes, copy number 8–9 (broad region; genes not listed).
- chr6:17,381,367–17,382,120, 1 gene, copy number 45: AL034372.1.
- chr6:19,892,397–21,602,383, 24 genes, copy number 34–46: AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3.
- chr6:22,569,566–23,649,774, 8 genes, copy number 7: HDGFL1, AL033539.1, AL033539.2, AL035401.1, AL591416.1, RNU6-1060P, AL139231.1, AL133270.1.
- chr6:61,574,328–61,681,049, 2 genes, copy number 7: MTRNR2L9, KHDRBS2-OT1.
- chr6:61,870,097–61,893,882, 1 gene, copy number 7: AL355347.1.
- chr7:53,490,148–56,687,366, 95 genes, copy number 8–33 (broad region; genes not listed).
- chr9:81,410,279–83,596,584, 34 genes, copy number 16: RPS20P25, AL161727.1, TLE1, AL591368.1, RNU6-1035P, RNA5SP287, AL158154.1, SPATA31D5P, AL158154.2, SPATA31D4, AL158154.3, SPATA31D3, SPATA31D2P, AL162726.3, SPATA31D1, SPATA31B1P, DDX10P2, AL158047.1, AL162726.1, MTCO3P40, AL162726.2, AL162726.4, AL356490.1, AL353774.1, RPS6P12, RASEF, AL499602.1, RN7SKP242, AL137847.3, AL137847.1, FRMD3, AL137847.2, RNU4-29P, RNU4-15P.
- chr10:2,150,480–19,790,401, 297 genes, copy number 7–16 (within-gene range 6–16) (broad region; genes not listed).
- chr10:28,743,506–28,941,910, 1 gene, copy number 7 (within-gene range 6–7): LINC01517.
- chr10:28,812,899–28,899,484, 3 genes, copy number 7: AL355376.2, RNA5SP308, RPL21P93.
- chr12:66,347,431–68,234,686, 26 genes, copy number 10–22 (within-gene range 6–22): GRIP1, OSBPL9P5, OSBPL9P4, AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, AC078983.1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26.
- chr12:68,805,011–70,243,379, 34 genes, copy number 27 (within-gene range 6–27): AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821.
- chr12:115,878,748–118,738,511, 51 genes, copy number 8: AC012157.3, MED13L, AC012157.2, RNU6-1188P, MIR620, SNRPGP18, AC130895.1, AC079384.2, AC079384.1, MIR4472-2, LINC02457, LINC00173, MAP1LC3B2, AC125603.4, AC125603.3, AC125603.2, AC125603.1, SPRING1, RNFT2, AC090013.1, RNU6-558P, AC083806.3, HRK, AC083806.1, FBXW8, AC083806.2, AC127164.1, AC026368.1, TESC, TESC-AS1, FBXO21, NOS1, ELOCP32, AC073864.1, KSR2, AC084291.1, RFC5, AC131159.2, WSB2, AC131159.1, VSIG10, AC131238.1, PEBP1, TAOK3, RPS2P5, AC026367.1, SUDS3, AC026367.3, AC026367.2, LINC02460, RPL17P37.
- chr12:121,132,819–123,662,604, 97 genes, copy number 7 (broad region; genes not listed).
- chr16:65,141,751–65,234,914, 2 genes, copy number 7 (within-gene range 7–10): LINC02126, AC009055.2.
- chr17:39,603,536–39,997,959, 21 genes, copy number 8: NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3.
- chr19:32,581,190–36,014,239, 174 genes, copy number 7–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
